Somatic mutation profile of tumor specimen TCGA-42-2582-01A (aliquot TCGA-42-2582-01A-01D-1526-09) from TCGA case TCGA-42-2582, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 49.2 years (17,961 days).
Specimen TCGA-42-2582-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b2bd7b6-1183-432f-a90d-9bf7010328cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-42-2582-10A (Blood Derived Normal), aliquot TCGA-42-2582-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5c3f93c-2a2b-4eba-8601-4760bcb76627

The open-access MAF lists 121 somatic variants for this specimen: 100 protein-altering or splice-affecting, 17 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 17, Frame Shift Del 3, Splice Site 2, Nonsense Mutation 2, RNA 2, In Frame Del 1, Frame Shift Ins 1, 3'UTR 1, Translation Start Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 39/89 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABHD14A | c.716A>T p.H239L | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); catalogued as COSV56473189, COSV56473451; called by muse, mutect2, varscan2
- ABI2 | c.1528C>T p.H510Y (on ENST00000295851 / NM_001375719.1; = p.H472Y on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/363 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV53694618; called by muse, mutect2, varscan2
- ANO7 | c.2560G>C p.V854L (on ENST00000274979; = p.V800L on NM_001370694.2) | Missense Mutation (SNP) | VAF 31/283 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV51475823, COSV99237092; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1470A>C p.L490F | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated (0.96); PolyPhen benign (0.206); catalogued as COSV63438627; called by muse, mutect2, varscan2
- ATF2 | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51372137; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1309G>C p.A437P | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99369604; called by muse, mutect2
- BCL3 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51234665; called by muse, mutect2, varscan2
- BRINP2 | c.2086G>A p.A696T | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); catalogued as COSV100838448; called by muse, mutect2, varscan2
- BTG4 | c.577G>T p.G193C | Missense Mutation (SNP) | VAF 16/279 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV100604619; called by muse, mutect2
- CACNG4 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs1258502203, COSV50924096; called by muse, mutect2
- CALCR | c.13T>C p.F5L | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1249755640, COSV64010532; called by muse, mutect2, varscan2
- CALCRL | c.407A>T p.K136M | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as COSV66476330; called by muse, mutect2, varscan2
- CELA2A | c.655C>A p.P219T | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62747220, COSV62747873; called by muse, varscan2
- CLCA2 | c.1193A>G p.K398R | Missense Mutation (SNP) | VAF 7/198 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as COSV100991742; called by muse, mutect2
- CNGA2 | c.470T>A p.L157Q | Missense Mutation (SNP) | VAF 63/283 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV61705545; called by muse, mutect2, varscan2
- COPS5 | c.574G>C p.G192R | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV100770033; called by muse, mutect2
- CYP27A1 | c.1220T>C p.I407T | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV51469453; called by muse, mutect2, varscan2
- DNASE2 | c.935T>G p.M312R | Missense Mutation (SNP) | VAF 54/357 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV52251442; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1615T>A p.Y539N | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as COSV50052409; called by muse, mutect2, varscan2
- DYNAP | c.300+2T>A p.X100_splice (on ENST00000321600; = p.X74_splice on NM_173629.3) | Splice Site (SNP) | VAF 63/194 reads (32%) | catalogued as rs768240268, COSV58666699; called by muse, mutect2, varscan2
- EFCAB14 | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 52/449 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as COSV64240173; called by muse, mutect2, varscan2
- EML4 | c.545A>G p.H182R | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV59302381; called by muse, mutect2, varscan2
- ENPP1 | c.1264T>C p.S422P | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100719649; called by muse, mutect2
- ERRFI1 | c.193A>G p.I65V | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV101088306; called by muse, mutect2
- FEZF1 | c.573C>A p.H191Q | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV58659301; called by muse, mutect2, varscan2
- FUT3 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 67/200 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs551619908, COSV54607310; called by muse, mutect2, varscan2
- GABRA4 | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 36/136 reads (26%) | catalogued as COSV51932082, COSV51932217; called by muse, mutect2, varscan2
- GAK | c.3230C>T p.S1077F | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as COSV100034078, COSV104404126; called by muse, mutect2
- GAS2 | c.786T>G p.Y262* | Nonsense Mutation (SNP) | VAF 18/260 reads (7%) | catalogued as COSV99535734; called by muse, mutect2
- GATA6 | c.1448T>C p.M483T | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as CD1110622, COSV52526980; called by muse, mutect2, varscan2
- GOLM2 | c.551C>G p.A184G | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.493); catalogued as COSV55465279; called by muse, mutect2, varscan2
- GP2 | c.646A>G p.N216D (on ENST00000381362 / NM_001007240.3; = p.N213D on NM_001502.4) | Missense Mutation (SNP) | VAF 36/359 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.354); catalogued as COSV100221660; called by muse, mutect2
- GPR137B | c.189G>C p.Q63H | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV63991369; called by muse, mutect2, varscan2
- GRHL3 | c.1427C>G p.P476R (on ENST00000350501 / NM_198174.3; = p.P481R on NM_021180.3) | Missense Mutation (SNP) | VAF 62/217 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as COSV52567573, COSV52569521; called by muse, mutect2, varscan2
- HDAC8 | c.676A>G p.S226G | Missense Mutation (SNP) | VAF 15/307 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV101003373; called by muse, mutect2
- IGHMBP2 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 107/327 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as rs556292818, COSV54824647; called by muse, mutect2, varscan2
- IL17RA | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs573583763, COSV60054941; called by muse, mutect2, varscan2
- IL7R | c.526A>T p.N176Y | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as COSV57411211; called by muse, mutect2
- IRGC | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as rs1372475411, COSV54983331; called by muse, mutect2
- KANSL1L | c.266T>C p.L89S | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55995021; called by muse, mutect2, varscan2
- KCNRG | c.187G>T p.D63Y | Missense Mutation (SNP) | VAF 27/205 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53950762; called by muse, mutect2, varscan2
- MACC1 | c.1288C>A p.P430T | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.738); catalogued as COSV60545073; called by muse, mutect2, varscan2
- MCF2L2 | c.2114G>T p.R705I | Missense Mutation (SNP) | VAF 7/159 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100193981; called by muse, mutect2
- MEIS2 | c.55G>C p.V19L (on ENST00000561208 / NM_170675.5; = p.V6L on NM_002399.3) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.005); catalogued as COSV54941575; called by muse, mutect2, varscan2
- MERTK | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 69/200 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745461381, COSV54928816; called by muse, mutect2, varscan2
- MME | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.682); catalogued as COSV64709189; called by muse, mutect2, varscan2
- MYO6 | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV100889424; called by muse, mutect2, varscan2
- MYO6 | c.629T>C p.V210A | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100889425; called by muse, mutect2, varscan2
- NAP1L3 | c.678A>C p.E226D | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as COSV59076825; called by muse, mutect2, varscan2
- NKTR | c.3002A>G p.K1001R | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); catalogued as COSV51773926; called by muse, mutect2, varscan2
- NLRP13 | c.2634G>C p.Q878H | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.153); catalogued as COSV61620540, COSV61623304; called by muse, mutect2, varscan2
- NLRP3 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as rs180177430, CM021073, CM060238, COSV60230837; ClinVar: not provided; called by muse, mutect2
- NUDT17 | c.812T>C p.M271T | Missense Mutation (SNP) | VAF 23/272 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782780442, COSV100566864; called by muse, mutect2
- OR10S1 | c.559C>G p.H187D | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as COSV73342933; called by muse, mutect2, varscan2
- OR6C4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 18/55 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV67793130; called by muse, mutect2, varscan2
- PACC1 | c.544C>G p.L182V | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.183); catalogued as COSV54788993; called by muse, mutect2, varscan2
- PALLD | c.1139C>G p.A380G | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as COSV54988992; called by muse, mutect2, varscan2
- PCDH12 | c.3362T>G p.L1121R | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99191440; called by muse, mutect2
- PDE1C | c.1559G>C p.R520T | Missense Mutation (SNP) | VAF 80/297 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV58522419; called by muse, mutect2, varscan2
- PDE4A | c.846G>C p.Q282H (on ENST00000380702 / NM_001111307.2; = p.Q43H on NM_006202.3) | Missense Mutation (SNP) | VAF 116/844 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV53359917; called by muse, mutect2, varscan2
- PHC2 | c.2466C>G p.D822E (on ENST00000257118 / NM_198040.2; = p.D287E on NM_004427.4) | Missense Mutation (SNP) | VAF 32/236 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57106508; called by muse, mutect2, varscan2
- PIAS3 | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 30/388 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs782054912, COSV100566862; called by muse, mutect2
- PRR14 | c.1019C>A p.P340H | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV54911100, COSV54913020; called by muse, mutect2, varscan2
- PTPRD | c.5706G>T p.E1902D | Missense Mutation (SNP) | VAF 122/354 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV61968754; called by muse, mutect2, varscan2
- PUS10 | c.1436A>C p.K479T | Missense Mutation (SNP) | VAF 92/236 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.183); catalogued as COSV57453906; called by muse, mutect2, varscan2
- RAB3IP | c.1281C>G p.I427M (on ENST00000550536 / NM_175623.4; = p.I411M on NM_022456.5) | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs767382883, COSV56085416; called by muse, mutect2, varscan2
- RABEPK | c.74G>C p.G25A | Missense Mutation (SNP) | VAF 86/342 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as COSV52337311; called by muse, mutect2, varscan2
- RNF111 | c.1858G>T p.G620C | Missense Mutation (SNP) | VAF 13/207 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.525); catalogued as COSV100789213; called by muse, mutect2
- SAGE1 | c.2017A>T p.T673S | Missense Mutation (SNP) | VAF 79/372 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.259); catalogued as COSV61015883; called by muse, mutect2, varscan2
- SART3 | c.1382A>G p.E461G (on ENST00000228284; = p.E443G on NM_014706.4) | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV57209490; called by muse, mutect2, varscan2
- SEC13 | c.790G>C p.V264L (on ENST00000350697 / NM_183352.3; = p.V267L on NM_030673.4) | Missense Mutation (SNP) | VAF 91/423 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.653); catalogued as COSV61602173; called by muse, mutect2, varscan2
- SGK2 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 8/273 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV100414845; called by muse, mutect2
- SKIL | c.310C>G p.P104A | Missense Mutation (SNP) | VAF 72/187 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52061551; called by muse, mutect2, varscan2
- SLC12A9 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 59/255 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51935764; called by muse, mutect2, varscan2
- SLC22A8 | c.637G>C p.A213P | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV60326258; called by muse, mutect2, varscan2
- SLC45A1 | c.2213A>T p.D738V | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV57098401; called by muse, mutect2, varscan2
- SLC4A11 | c.1463G>T p.R488M | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM072051, COSV66263148; called by muse, mutect2, varscan2
- SLC5A4 | c.1173G>A p.M391I | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as COSV56671158, COSV99832144; called by muse, mutect2
- SLCO1B1 | c.513G>T p.W171C | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57009953, COSV57014552; called by muse, mutect2, varscan2
- SOD1 | c.181G>C p.A61P | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54256823; called by muse, mutect2, varscan2
- SRI | c.590G>A p.S197N | Missense Mutation (SNP) | VAF 53/249 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1401209252, COSV56001166; called by muse, mutect2, varscan2
- SSRP1 | c.1449C>G p.N483K | Missense Mutation (SNP) | VAF 130/453 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV53480680; called by muse, mutect2, varscan2
- STXBP2 | c.1383G>T p.E461D | Missense Mutation (SNP) | VAF 73/457 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV55404772; called by muse, mutect2, varscan2
- TCF23 | c.575C>A p.S192Y | Missense Mutation (SNP) | VAF 115/370 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV56078804; called by muse, mutect2, varscan2
- TENM1 | c.17G>A p.C6Y | Missense Mutation (SNP) | VAF 45/203 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.202); catalogued as COSV100949567, COSV64438535; called by muse, mutect2, varscan2
- THAP4 | c.257A>C p.H86P | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.601); catalogued as COSV101126081; called by muse, mutect2, varscan2
- TOMM40L | c.331G>T p.V111F | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as COSV63468869; called by muse, mutect2, varscan2
- TRIM69 | c.11C>A p.S4Y | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV100274419; called by muse, mutect2, varscan2
- TSNARE1 | c.432C>G p.H144Q | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); catalogued as COSV100211491, COSV56181874; called by muse, mutect2
- TTC14 | c.486+1G>T p.X162_splice | Splice Site (SNP) | VAF 98/296 reads (33%) | catalogued as COSV56013289; called by muse, mutect2, varscan2
- TTI1 | c.2131C>G p.L711V | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.03); catalogued as COSV65062677; called by muse, mutect2, varscan2
- UTP25 | c.448T>G p.S150A | Missense Mutation (SNP) | VAF 88/256 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV101530939, COSV72227475; called by muse, mutect2, varscan2
- WWC3 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs771181004, COSV66503596; called by muse, mutect2, varscan2
- ADAMTS4 | c.1995C>G p.I665M | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.027); called by muse, mutect2
- CHUK | c.1284_1294del p.E429Lfs*10 | Frame Shift Del (DEL) | VAF 74/242 reads (31%) | called by mutect2, pindel, varscan2
- DKK1 | c.604_638del p.A202Pfs*11 | Frame Shift Del (DEL) | VAF 20/108 reads (19%) | called by mutect2, pindel
- FOXN1 | c.1633_1634del p.L545Vfs*7 | Frame Shift Del (DEL) | VAF 48/100 reads (48%) | called by mutect2, pindel, varscan2
- HDAC4 | c.475_477del p.E159del | In Frame Del (DEL) | VAF 75/233 reads (32%) | called by mutect2, pindel, varscan2
- SLC7A14 | c.2223_2226dup p.T743Pfs*4 | Frame Shift Ins (INS) | VAF 226/776 reads (29%) | called by mutect2, varscan2
- ADSS1 | c.1317C>T p.V439= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as COSV58275221; called by muse, mutect2, varscan2
- CDC42BPB | c.3861T>G p.A1287= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV63476212; called by muse, varscan2
- CFAP65 | c.3921C>T p.I1307= | Silent (SNP) | VAF 106/351 reads (30%) | catalogued as COSV58564328; called by muse, mutect2, varscan2
- CSN2 | c.45A>C p.A15= | Silent (SNP) | VAF 46/130 reads (35%) | catalogued as rs1392413559, COSV61992436; called by muse, mutect2, varscan2
- FLCN | c.675C>G p.A225= | Silent (SNP) | VAF 10/234 reads (4%) | catalogued as COSV99550732; called by muse, mutect2
- INSL6 | c.7C>A p.R3= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV67563254; called by muse, mutect2, varscan2
- KAT7 | c.1650G>A p.V550= | Silent (SNP) | VAF 18/292 reads (6%) | catalogued as COSV52013918, COSV99372085; called by muse, mutect2
- KDM3B | c.5274G>A p.L1758= | Silent (SNP) | VAF 64/218 reads (29%) | catalogued as COSV54735601; called by muse, mutect2, varscan2
- MAGEF1 | c.681G>A p.R227= | Silent (SNP) | VAF 23/166 reads (14%) | catalogued as COSV58634186; called by muse, mutect2, varscan2
- MDN1 | c.8775C>T p.T2925= | Silent (SNP) | VAF 10/270 reads (4%) | catalogued as COSV101021839; called by muse, mutect2
- PARP9 | c.447G>C p.L149= | Silent (SNP) | VAF 6/118 reads (5%) | catalogued as COSV100831269; called by muse, mutect2
- PDE3A | c.1386C>T p.R462= | Silent (SNP) | VAF 129/368 reads (35%) | catalogued as COSV62979008; called by muse, mutect2, varscan2
- PIEZO2 | c.7869A>C p.T2623= | Silent (SNP) | VAF 14/246 reads (6%) | catalogued as COSV99555524; called by muse, mutect2
- PLS3 | c.1416T>C p.H472= | Silent (SNP) | VAF 27/283 reads (10%) | catalogued as COSV99172383; called by muse, mutect2
- SCGB1D1 | c.171A>C p.A57= | Silent (SNP) | VAF 87/293 reads (30%) | catalogued as COSV60377865; called by muse, mutect2, varscan2
- SFXN4 | c.453C>T p.I151= | Silent (SNP) | VAF 25/246 reads (10%) | catalogued as COSV100341248; called by muse, mutect2, varscan2
- USP8 | c.1125G>A p.L375= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV56166683; called by muse, mutect2, varscan2
- DUSP13 | c.*120G>T | 3'UTR (SNP) | VAF 36/129 reads (28%) | catalogued as COSV57815573; called by muse, mutect2, varscan2
- MIR512-2 | n.10C>T | RNA (SNP) | VAF 19/64 reads (30%) | catalogued as rs768629652; called by muse, mutect2, varscan2
- SLC22A17 | n.782G>T | RNA (SNP) | VAF 47/132 reads (36%) | catalogued as COSV52836612; called by muse, mutect2, varscan2
- TAOK2 | chr16:29991518 A>T | 3'Flank (SNP) | VAF 11/32 reads (34%) | catalogued as COSV54231189; called by muse, mutect2, varscan2
